Surgical pathology report (de-identified scan), TCGA case TCGA-08-0352, project TCGA-GBM (Glioblastoma Multiforme), tissue source site UCSF, specimen TCGA-08-0352-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

TCGA-08-0352

FINAL PATHOLOGIC DIAGNOSIS

Brain tumor, biopsy: WHO glioblastoma multiforme, grade IV; see comment.

COMMENT: There are highly cellular regions of neoplastic astrocytes accompanied by extensive microvascular proliferation and areas of necrosis.

Intraoperative Diagnosis

FS1 (A) Brain tumor, biopsy: WHO glioblastoma multiforme, grade IV. Tissue section and cytologic preparation.

Gross Description

The specimen, received fresh in the O.R. in one part, labeled with the patient's name, medical record number and "brain tumor," consists of five unoriented, soft, pink-tan, irregularly shaped tissue fragments measuring 1.1 x 0.5 x 0.2 cm in aggregate. Two fragments are submitted for frozen section diagnosis # 1, with the remnant submitted in cassette A1. The remaining tissue is entirely submitted in cassette A2.

Clinical History

with a right temporal enhancing mass, who undergoes resection.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Source: NCI Genomic Data Commons file e2e1ab23-967c-48de-bd9a-965027aeb2ab (TCGA-08-0352.8FD1D361-A630-4D7D-AD4F-0C6399F6CB23.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).